Somatic mutation profile of tumor specimen MP2PRT-PAPZKC-TMP1-A (aliquot MP2PRT-PAPZKC-TMP1-A-1-0-D-A83B-36) from MP2PRT case MP2PRT-PAPZKC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.0 years (718 days).
Specimen MP2PRT-PAPZKC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c31b61d3-994f-446e-80c1-01a982dce45f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPZKC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPZKC-NB1-A-1-0-D-A83B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2949cc93-91ea-46cb-80d2-91dbf4ff2ede

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 45/120 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- GPR83 | c.962G>A p.R321H | Missense Mutation (SNP) | VAF 197/506 reads (39%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs145628763, COSV54717571; called by muse, mutect2, varscan2
- PIR | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 113/304 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as rs773172117; called by muse, mutect2, varscan2
- URB1 | c.6074G>A p.R2025Q | Missense Mutation (SNP) | VAF 141/750 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as rs1436183626; called by muse, mutect2, varscan2
- INTS3 | c.2531T>C p.L844P | Missense Mutation (SNP) | VAF 221/530 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NFATC1 | c.111G>T p.M37I | Missense Mutation (SNP) | VAF 118/394 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TFB2M | c.1076A>G p.D359G | Missense Mutation (SNP) | VAF 98/256 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATXN1 | c.942G>A p.L314= | Silent (SNP) | VAF 187/623 reads (30%) | called by muse, mutect2, varscan2
- MEGF6 | c.3546G>A p.P1182= | Silent (SNP) | VAF 163/392 reads (42%) | catalogued as rs928241807; called by muse, mutect2, varscan2
